FM case AD2694 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/eb009c1a-9f43-4c78-a505-79ee2ac38f8b

Female, 68.9 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the other ill-defined sites. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Tumor.
